Somatic mutation profile of tumor specimen TCGA-VS-A950-01A (aliquot TCGA-VS-A950-01A-11D-A42O-09) from TCGA case TCGA-VS-A950, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 42.1 years (15,365 days).
Specimen TCGA-VS-A950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be7dc44f-aa05-4343-89b0-5fa215eae295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A950-10B (Blood Derived Normal), aliquot TCGA-VS-A950-10B-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d2788be-4ac1-4236-b637-f50b44a3fbd0

The open-access MAF lists 119 somatic variants for this specimen: 85 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 32, Nonsense Mutation 8, Splice Region 2, RNA 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ACSF2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1200159122, COSV51973211; called by muse, mutect2, varscan2
- ACTG1 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV100111954; called by muse, mutect2, varscan2
- ACTG1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59511786; called by muse, mutect2, varscan2
- ADAMTS19 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50740525, COSV99177111, COSV99179030; called by muse, mutect2, varscan2
- AHCYL1 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100779598; called by muse, mutect2, varscan2
- AKAP12 | c.4723G>C p.E1575Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV99483500; called by muse, mutect2, varscan2
- AP3B2 | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV99916562; called by muse, mutect2, varscan2
- BSN | c.2476C>T p.L826F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV56515390, COSV99608664; called by muse, mutect2, varscan2
- BSN | c.4730C>T p.S1577F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99608667; called by muse, mutect2, varscan2
- C10orf88 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV64403595, COSV64403852; called by muse, mutect2, varscan2
- CACNA1F | c.3809C>T p.A1270V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.429); catalogued as rs868939184, COSV59903064; called by muse, mutect2, varscan2
- CCDC40 | c.2825G>A p.R942K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100884249; called by mutect2, varscan2
- CDC42BPA | c.4671G>A p.R1557= (on ENST00000334218 / NM_001366019.2; = p.R1544= on NM_003607.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100505498; called by muse, mutect2, varscan2
- CGNL1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as rs748763323, COSV99848417; called by muse, mutect2, varscan2
- CROCC | c.4129G>T p.E1377* | Nonsense Mutation (SNP) | VAF 6/9 reads (67%) | catalogued as COSV100978265; called by muse, mutect2, varscan2
- CRTAC1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs762285795, COSV54011157; called by muse, mutect2, varscan2
- CYP2A6 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs760744271, COSV99991869; called by muse, varscan2
- DCDC2 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.656); catalogued as COSV99219739; called by muse, mutect2, varscan2
- DCHS1 | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100202128; called by muse, mutect2, varscan2
- DCLK1 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99711565; called by muse, mutect2, varscan2
- DDX17 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs746498158, COSV53251027; called by muse, mutect2, varscan2
- DMAC2 | c.435C>T p.L145= | Splice Region (SNP) | VAF 26/88 reads (30%) | catalogued as COSV99700554; called by muse, mutect2, varscan2
- DNAAF1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs745857720, COSV57576563; called by muse, mutect2, varscan2
- DNAJC13 | c.6344G>A p.R2115Q | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.421); catalogued as rs770715465, CM141864, COSV53450154; called by muse, mutect2, varscan2
- DOCK4 | c.5132G>A p.R1711Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs747259595, COSV101447880; called by muse, mutect2, varscan2
- ETV5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100112350; called by muse, mutect2, varscan2
- EXO5 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 15/23 reads (65%) | catalogued as COSV56415899, COSV99591298; called by muse, mutect2, varscan2
- FAM13A | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99983843; called by muse, mutect2, varscan2
- GBF1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100890515; called by muse, mutect2, varscan2
- GPD2 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV100133304; called by muse, mutect2, varscan2
- GPR179 | c.2311A>G p.K771E (on ENST00000621958; = p.K770E on NM_001004334.4) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1280142501; called by muse, mutect2, varscan2
- GRM5 | c.2300A>G p.N767S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV100552322; called by muse, mutect2, varscan2
- GUCA1B | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV100027724; called by muse, mutect2, varscan2
- HS3ST5 | c.101T>A p.L34* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100451006; called by muse, mutect2, varscan2
- ITPR2 | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs745966022, COSV101190012; called by muse, mutect2, varscan2
- KCNK17 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100950193; called by muse, mutect2
- KDM2B | c.2078A>C p.E693A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100997437; called by muse, mutect2, varscan2
- KDM7A | c.2548G>A p.G850S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs758963637, COSV99134567; called by muse, mutect2, varscan2
- KIF7 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99176571; called by muse, mutect2, varscan2
- LTB4R | c.602A>T p.Y201F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99350781; called by muse, mutect2, varscan2
- MPHOSPH8 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV100825133; called by muse, mutect2, varscan2
- MRPL2 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99432055; called by muse, mutect2, varscan2
- MYO1H | c.2899G>A p.D967N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57328345, COSV99949293; called by muse, mutect2, varscan2
- NAV3 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762530428, COSV99891721; called by muse, mutect2, varscan2
- NIPBL | c.3853C>A p.H1285N | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99240861; called by muse, mutect2, varscan2
- NIPBL | c.3998T>C p.I1333T | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99240863; called by muse, mutect2, varscan2
- OR5H6 | c.676A>G p.T226A (on ENST00000642105; = p.T210A on NM_001005479.2) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV101051783; called by muse, mutect2, varscan2
- PCF11 | c.1571C>G p.S524C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.527); catalogued as COSV100018577, COSV53536556; called by muse, mutect2, varscan2
- PEX3 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100852170; called by muse, mutect2, varscan2
- PHLDB2 | c.2549C>G p.S850C (on ENST00000393925 / NM_001134439.2; = p.S807C on NM_145753.2) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs201249374, COSV101208549; called by muse, mutect2, varscan2
- PKHD1L1 | c.3730G>A p.D1244N | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV65737438; called by muse, mutect2, varscan2
- PLA2G3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV99311759; called by muse, mutect2, varscan2
- PLA2G5 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as rs200954922, CM1110073, COSV100908268, COSV99056073; ClinVar: affects; called by muse, mutect2, varscan2
- POTEE | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV100388102; called by muse, mutect2, varscan2
- POU4F1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101020559; called by muse, mutect2, varscan2
- PRB3 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99685798; called by muse, mutect2, varscan2
- PREX1 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs768227498, COSV100906400; called by muse, mutect2, varscan2
- PUS10 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100369565; called by muse, mutect2, varscan2
- RAP1GAP2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs867183095, COSV99623419; called by muse, mutect2, varscan2
- RC3H1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV99281414; called by muse, mutect2, varscan2
- RTL6 | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100373790; called by muse, mutect2, varscan2
- SDK2 | c.4282G>A p.G1428R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749315984, COSV101166587; called by muse, mutect2, varscan2
- SEMA3E | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV100318748; called by muse, mutect2, varscan2
- SGIP1 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV99391756; called by muse, mutect2, varscan2
- SOGA1 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99414112; called by muse, mutect2, varscan2
- SRPK3 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782293883, COSV99473203; called by muse, mutect2, varscan2
- SUMO1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101108630; called by muse, mutect2
- SUPT16H | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99359922; called by muse, mutect2, varscan2
- SUPT20H | c.561G>A p.W187* (on ENST00000350612 / NM_001014286.3; = p.W188* on NM_017569.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/92 reads (47%) | catalogued as COSV100634702; called by muse, mutect2, varscan2
- TIAL1 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV100958425; called by muse, mutect2, varscan2
- TIMP2 | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV99430517; called by muse, mutect2, varscan2
- TM9SF3 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100951857; called by muse, mutect2, varscan2
- TMEM63C | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100029470; called by muse, mutect2, varscan2
- TOPBP1 | c.2596G>T p.V866F | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99605398; called by muse, mutect2, varscan2
- TRDMT1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs141411248; called by muse, mutect2, varscan2
- TSHZ2 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as rs763569165, COSV100296193; called by muse, mutect2, varscan2
- UNC13A | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV99408509; called by muse, mutect2, varscan2
- USPL1 | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99687326; called by muse, mutect2, varscan2
- VASH1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51335364; called by muse, mutect2, varscan2
- ZNF546 | c.1583A>G p.N528S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100713468; called by muse, mutect2, varscan2
- CCZ1 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.276); called by mutect2, varscan2
- CHRNB1 | c.891A>C p.K297N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2
- UQCRHL | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF112 | c.685_689del p.E229Lfs*5 (on ENST00000337401 / NM_001083335.2; = p.E223Lfs*5 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- ATG4D | c.543G>T p.G181= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs766303951, COSV100521035; called by muse, mutect2, varscan2
- ATP2A2 | c.1335C>T p.L445= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs747229006, COSV100428647; called by muse, mutect2, varscan2
- BACH2 | c.1716C>T p.Y572= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99999788; called by muse, mutect2, varscan2
- BRWD3 | c.4278T>C p.H1426= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV100956140; called by muse, mutect2, varscan2
- CACNA1B | c.351C>T p.H117= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1441554381, COSV99497891; called by muse, mutect2, varscan2
- CASZ1 | c.3831C>T p.F1277= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as rs1489203211, COSV100681526; called by muse, mutect2, varscan2
- CD84 | c.540C>T p.I180= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs1452229493, COSV100246057; called by muse, mutect2, varscan2
- DCAF1 | c.3009G>A p.T1003= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs542435236, COSV100244101; called by muse, mutect2, varscan2
- DCDC1 | c.2232G>A p.Q744= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1486303922, COSV100663536; called by muse, mutect2, varscan2
- FMOD | c.924C>T p.I308= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV61609938, COSV61610284; called by muse, varscan2
- FMOD | c.870C>T p.F290= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100724556; called by muse, varscan2
- GAL3ST1 | c.1014C>T p.N338= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100143110; called by muse, mutect2, varscan2
- GPER1 | c.624C>T p.F208= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1457224939, COSV99867118; called by muse, mutect2, varscan2
- KLHL30 | c.1518C>T p.G506= | Silent (SNP) | VAF 62/83 reads (75%) | catalogued as rs545573277, COSV100014351; called by muse, mutect2, varscan2
- LRP1 | c.11889C>T p.I3963= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs751160605, COSV99676035; called by muse, mutect2, varscan2
- LRRK2 | c.633G>A p.A211= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs199915040, COSV54167235; called by muse, mutect2, varscan2
- NUCB1 | c.447C>T p.F149= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs755935622, COSV54385315; called by muse, mutect2, varscan2
- OPHN1 | c.1656G>C p.V552= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100830507; called by muse, mutect2, varscan2
- PCK1 | c.1023G>A p.V341= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100100552; called by muse, mutect2, varscan2
- PEX3 | c.336C>T p.F112= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100852169; called by muse, mutect2, varscan2
- PHOSPHO1 | c.111C>T p.I37= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1352845658, COSV99865606; called by muse, mutect2, varscan2
- POTEE | c.2136C>T p.N712= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as rs1488580379, COSV100388105; called by muse, mutect2, varscan2
- PRAF2 | c.162C>T p.I54= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs782764657, COSV100540278; called by muse, mutect2
- PRSS54 | c.156G>A p.E52= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1428678552, COSV99541639; called by muse, mutect2, varscan2
- RBL2 | c.1107G>A p.L369= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100043702; called by muse, mutect2, varscan2
- SNUPN | c.909G>C p.G303= | Silent (SNP) | VAF 46/84 reads (55%) | catalogued as COSV100419398; called by muse, mutect2, varscan2
- SYNE1 | c.21027A>G p.L7009= (on ENST00000367255 / NM_182961.4; = p.L6938= on NM_033071.3) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs757354550, COSV99566687; called by muse, mutect2, varscan2
- SYNE1 | c.15052C>T p.L5018= (on ENST00000367255 / NM_182961.4; = p.L4947= on NM_033071.3) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99566692; called by muse, mutect2, varscan2
- TMEM202 | c.378C>T p.V126= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100499176; called by muse, mutect2, varscan2
- UBFD1 | c.792C>T p.I264= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99563298; called by muse, mutect2, varscan2
- VPS13B | c.4743G>A p.L1581= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs1322804531, COSV100662218; called by muse, mutect2, varscan2
- ZNF286A | c.120A>G p.R40= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV101224692; called by muse, mutect2, varscan2
- OR2W5 | n.564G>A | RNA (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1502G>T | RNA (SNP) | VAF 7/27 reads (26%) | catalogued as COSV52837463, COSV52837905, COSV99248835; called by muse, mutect2, varscan2
